Gene-level copy-number profile of tumor specimen TCGA-CU-A3QU-01A from TCGA case TCGA-CU-A3QU, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Bladder, NOS; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 58.1 years (21,233 days).
Specimen TCGA-CU-A3QU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.b13f7500-4d1f-4790-98a3-776cf7a4d58e.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CU-A3QU-10B (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a2461cae-57c8-4342-acd1-42e27c23f9d3

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 55; copy number 1: 669; copy number 2: 12,742; copy number 3: 11,401; copy number 4: 26,741; copy number 5: 5,441; copy number 6: 1,580; copy number 7: 472; copy number 8: 654; copy number 10: 55.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CU-A3QU-01A-11D-A22Y-01): tumor purity 0.9, ploidy 3.6, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 55 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:48,232,612–50,125,720, 51 genes: ITM2B, RB1-DT, RB1, PPP1R26P1, PCNPP5, AL392048.1, LPAR6, Metazoa_SRP, RCBTB2, AL157813.2, AL157813.1, LINC01077, LINC00462, CYSLTR2, PSME2P2, AL161421.1, FNDC3A, RNU6-60P, RAD17P2, RNY3P2, COX7CP1, OGFOD1P1, MLNR, AL137000.1, CDADC1, CAB39L, SETDB2, SNRPGP14, PHF11, RCBTB1, AL135901.1, ARL11, EBPL, KPNA3, AL136301.1, RNY4P30, CTAGE10P, RNY4P9, SPRYD7, DLEU2, TRIM13, MIR3613, KCNRG, AL137060.9, AL137060.7, MIR16-1, MIR15A, AL137060.4, AL137060.2, AL137060.8, AL137060.5.
- chr13:50,082,295–50,128,463, 4 genes: AL137060.6, RPL18P10, AL137060.1, AL137060.3.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 55 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:11,668,455–14,275,600, 53 genes, copy number 10: SNN, TXNDC11, AC007613.1, ZC3H7A, Metazoa_SRP, AC010654.1, BCAR4, RSL1D1, AC007216.4, GSPT1, AC007216.3, COX6CP1, AC007216.2, AC007216.5, NPIPB2, TNFRSF17, UBL5P4, SNX29, AC007216.1, RPS23P6, AC007601.1, AC007601.2, AC092365.1, AC007598.2, AC007598.1, AC007598.3, AC131391.1, AC010333.1, AC010333.2, AC010333.3, CPPED1, MIR4718, AC109597.1, AC109597.2, AC092324.1, RPL35AP34, SHISA9, AC009134.1, U91319.1, AC003009.1, TMF1P1, U95743.1, ERCC4, RPS26P52, AC010401.1, AC010401.2, LINC02185, LINC02186, MRTFB, AC130650.2, AC130650.1, TVP23CP2, Y_RNA.
- chr16:14,303,967–14,309,371, 2 genes, copy number 10: MIR193B, MIR365A.

Autosomal genes at a single copy (total copy number 1): 669. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
